Somatic mutation profile of tumor specimen MP2PRT-PANSHK-TMP1-A (aliquot MP2PRT-PANSHK-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANSHK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (837 days).
Specimen MP2PRT-PANSHK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 175a815d-1387-4f6d-86ea-fafe7e1e5df0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANSHK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANSHK-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211b1e62-36cb-4217-a337-1b1891da2423

The open-access MAF lists 73 somatic variants for this specimen: 45 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 26, Nonsense Mutation 6, Intron 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4B | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as COSV51608682, COSV99936575; called by muse, mutect2, varscan2
- CALR3 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 15/473 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54169678; called by muse, mutect2
- CASKIN1 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 143/652 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs777007261; called by muse, mutect2, varscan2
- CHMP6 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 133/650 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs946123498, COSV57327213; called by muse, mutect2, varscan2
- COL12A1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.169); catalogued as COSV59403847; called by muse, mutect2, varscan2
- DDX46 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV62799158; called by muse, mutect2, varscan2
- DST | c.8798C>T p.S2933L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1331685805; called by muse, mutect2
- EPOR | c.1278C>G p.Y426* | Nonsense Mutation (SNP) | VAF 40/684 reads (6%) | catalogued as rs121917831, CM980611; ClinVar: affects; called by muse, mutect2
- FAM168A | c.449G>A p.G150E (on ENST00000064778 / NM_001286050.2; = p.G141E on NM_015159.3) | Missense Mutation (SNP) | VAF 92/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50359450; called by muse, mutect2, varscan2
- GOLGB1 | c.7531G>A p.E2511K | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100510821, COSV61469198; called by muse, mutect2, varscan2
- HLF | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 38/748 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs199742593, COSV56829793; called by muse, mutect2
- HUWE1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV53359922; called by muse, mutect2, varscan2
- LAMC2 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV51457247; called by muse, mutect2, varscan2
- MC4R | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 93/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs13447332, CM121075, CM990834, COSV55352467; called by muse, mutect2, varscan2
- OR1M1 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV104436525; called by muse, mutect2, varscan2
- PAG1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 88/376 reads (23%) | catalogued as COSV55060656; called by muse, mutect2, varscan2
- PLPP7 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 150/621 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs772544361; called by muse, mutect2, varscan2
- PPP2R2D | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 300/542 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV70779581; called by muse, mutect2, varscan2
- PRPF6 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV53875944; called by muse, mutect2, varscan2
- RFT1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV56249871; called by muse, mutect2, varscan2
- SCIN | c.1664G>C p.G555A (on ENST00000297029 / NM_001112706.3; = p.G308A on NM_033128.3) | Missense Mutation (SNP) | VAF 79/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698758; called by muse, mutect2, varscan2
- SETD1A | c.3748G>C p.E1250Q | Missense Mutation (SNP) | VAF 184/775 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.543); catalogued as COSV52691070; called by muse, mutect2, varscan2
- SORBS1 | c.3057C>A p.D1019E | Missense Mutation (SNP) | VAF 70/584 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs1333272948; called by muse, mutect2, varscan2
- SRGAP1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 97/494 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1395401551; called by muse, mutect2, varscan2
- SYT1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54052521; called by muse, mutect2
- TBC1D8 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868408568; called by muse, mutect2, varscan2
- UBR4 | c.4865C>G p.S1622* | Nonsense Mutation (SNP) | VAF 75/442 reads (17%) | catalogued as COSV64396013; called by muse, mutect2, varscan2
- ZNF217 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56600698; called by muse, mutect2, varscan2
- ZNF551 | c.1991T>C p.V664A | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV56594364; called by muse, mutect2
- ZNF566 | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 75/296 reads (25%) | catalogued as COSV67573425; called by muse, mutect2, varscan2
- AIRE | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 101/571 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATM | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- ATP8A2 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- B3GNT10 | c.9G>A p.V3= | Splice Region (SNP) | VAF 53/240 reads (22%) | called by muse, mutect2, varscan2
- BNC2 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- COG8 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 262/905 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- LRIG3 | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- PATL2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 106/430 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SLC35G5 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 63/568 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TMSB4Y | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TOPBP1 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TPBG | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 32/840 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.306); called by muse, mutect2
- USP15 | c.1975G>A p.D659N (on ENST00000280377 / NM_001351159.2; = p.D630N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2
- VPS72 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.203); called by muse, mutect2
- ZSWIM3 | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 213/540 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADGRB3 | c.981C>T p.S327= | Silent (SNP) | VAF 68/343 reads (20%) | catalogued as rs1033505820, COSV65386694, COSV65395370; called by muse, mutect2, varscan2
- AMOTL1 | c.1236G>A p.P412= | Silent (SNP) | VAF 140/695 reads (20%) | catalogued as rs756448740, COSV58568591; called by muse, mutect2, varscan2
- CCDC71 | c.663G>C p.G221= | Silent (SNP) | VAF 36/532 reads (7%) | called by muse, mutect2
- CCN1 | c.165C>G p.V55= | Silent (SNP) | VAF 61/900 reads (7%) | called by muse, mutect2
- CMYA5 | c.9825G>A p.P3275= | Silent (SNP) | VAF 151/339 reads (45%) | catalogued as rs1025088693; called by muse, mutect2, varscan2
- CSMD3 | c.418C>T p.L140= | Silent (SNP) | VAF 25/211 reads (12%) | called by muse, mutect2, varscan2
- DUSP21 | c.114C>T p.N38= | Silent (SNP) | VAF 311/333 reads (93%) | catalogued as COSV59134726; called by muse, mutect2, varscan2
- EPHB2 | c.2940G>A p.Q980= (on ENST00000400191 / NM_001309193.2; = p.Q981= on NM_004442.7) | Silent (SNP) | VAF 83/448 reads (19%) | called by muse, mutect2, varscan2
- FKBP15 | c.1524C>T p.L508= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as COSV53037595, COSV53038069; called by muse, varscan2
- FSIP2 | c.19149T>C p.S6383= | Silent (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
- GPR155 | c.924G>A p.V308= | Silent (SNP) | VAF 92/431 reads (21%) | called by muse, mutect2, varscan2
- GRIN2B | c.10A>C p.R4= | Silent (SNP) | VAF 59/357 reads (17%) | catalogued as COSV74207229; called by muse, mutect2, varscan2
- IGLL1 | c.60C>G p.L20= | Silent (SNP) | VAF 53/856 reads (6%) | called by muse, mutect2
- ITPRIPL2 | c.291C>T p.L97= | Silent (SNP) | VAF 115/685 reads (17%) | called by muse, mutect2, varscan2
- MDN1 | c.5235G>A p.L1745= | Silent (SNP) | VAF 112/497 reads (23%) | called by muse, mutect2, varscan2
- PARVB | c.975G>A p.L325= | Silent (SNP) | VAF 90/457 reads (20%) | catalogued as COSV100114386; called by muse, mutect2, varscan2
- PCDHB10 | c.2109C>T p.F703= | Silent (SNP) | VAF 14/596 reads (2%) | called by muse, mutect2
- PCDHB6 | c.657G>A p.P219= | Silent (SNP) | VAF 20/658 reads (3%) | catalogued as COSV50715019, COSV50741249; called by muse, mutect2
- SAT2 | c.402G>A p.Q134= | Silent (SNP) | VAF 104/536 reads (19%) | catalogued as rs1391365115; called by muse, mutect2, varscan2
- TMEM14A | c.207G>C p.V69= | Silent (SNP) | VAF 46/176 reads (26%) | called by muse, mutect2, varscan2
- TMEM163 | c.75G>A p.A25= | Silent (SNP) | VAF 162/786 reads (21%) | catalogued as rs1559004252; called by muse, mutect2, varscan2
- USP21 | c.1215C>T p.P405= | Silent (SNP) | VAF 71/356 reads (20%) | called by muse, mutect2, varscan2
- VPS13B | c.111C>T p.L37= | Silent (SNP) | VAF 27/469 reads (6%) | called by muse, mutect2
- ZER1 | c.975G>A p.P325= | Silent (SNP) | VAF 30/522 reads (6%) | catalogued as rs140497395; called by muse, mutect2
- ZKSCAN7 | c.1614C>G p.L538= | Silent (SNP) | VAF 82/381 reads (22%) | catalogued as COSV99837586; called by muse, mutect2, varscan2
- ZNF514 | c.54G>A p.L18= | Silent (SNP) | VAF 121/504 reads (24%) | catalogued as COSV99728111; called by muse, mutect2, varscan2
- DST | c.4297-4232C>T | Intron (SNP) | VAF 56/220 reads (25%) | called by muse, mutect2, varscan2
- EMX2 | c.*379C>T | 3'UTR (SNP) | VAF 128/745 reads (17%) | catalogued as COSV71294528; called by muse, mutect2, varscan2
